Gene-level copy-number profile of tumor specimen TCGA-KK-A7B0-01A from TCGA case TCGA-KK-A7B0, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 67.8 years (24,756 days).
Specimen TCGA-KK-A7B0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.b892ebea-98bb-4d02-a0c0-31a8f113a0d0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-KK-A7B0-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/091e0d25-384b-44d0-a2a1-fe6e8d9ed14a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 33; copy number 1: 6,239; copy number 2: 50,494; copy number 3: 3,054.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-KK-A7B0-01A-11D-A32A-01): tumor purity 0.31, ploidy 1.96, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 33 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:88,507,546–90,016,720, 12 genes (within-gene range 0–2): LINC00461, H3P23, MIR9-2, MEF2C-AS2, AC008525.1, AC008525.2, MEF2C, MEF2C-AS1, AC074131.1, LINC02161, AC113167.1, MIR3660.
- chr5:100,806,933–101,976,798, 5 genes: ST8SIA4, MIR548P, RN7SL802P, OR7H2P, AC117525.1.
- chr8:61,057,158–62,249,879, 16 genes (within-gene range 0–1): CLVS1, NPM1P6, AC023866.2, AC023866.1, ASPH, KRT8P3, RN7SKP97, MIR4470, AC091173.1, LINC02842, AC025524.1, LINC02155, C1GALT1P3, NARS1P2, AC104852.1, AC023095.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 3,866. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
